Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17A-01A (Primary Tumor).

[page 1 of 9]
1/14/11

for

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, mixed clear cell and endometrioid types, is identified forming an 8.2 x 6.3 x 2.0 cm mass located in the anterior uterine wall. The tumor invades 1.2 cm into the myometrium (total myometrial thickness, 2.9 cm). The tumor involves the glandular epithelium of the endocervix. The ectocervix is negative for tumor. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are negative for tumor. [AJCC pT2a]

B-E. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (6 external iliac, 5 common iliac, 8 obturator) are negative for tumor. Specimen B submitted as "left pelvic lymph nodes, internal" did not contain nodal tissue.

F-I. Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (6 external iliac, 3 internal iliac, 6 common iliac, 12 obturator) are negative for tumor.

J. Lymph nodes, right para-aortic above the inferior mesenteric artery, excision: Multiple (6) lymph nodes are negative for tumor.

K. Lymph nodes, right para-aortic below the inferior mesenteric artery, excision: Multiple (3) lymph nodes are negative for tumor.

[page 2 of 9]
L. Gonadal vessels, right, excision: Negative for tumor.

M. Lymph nodes, left para-aortic above the inferior mesenteric artery, excision: Multiple (12) lymph nodes are negative for tumor.

N. Lymph nodes, left para-aortic below the inferior mesenteric artery, excision: Multiple (2) lymph nodes are negative for tumor.

O. Gonadal vessels, left, excision: Negative for tumor.

P. Omentum, omentectomy: Benign adipose tissue, negative for tumor.

Q-AA. Peritoneum; cul de sac, left colic gutter, left pelvic sidewall, small bowel serosa, large bowel serosa, bladder peritoneum, right colic gutter, right pelvic sidewall, small bowel mesentery, large bowel mesentery, right diaphragm; staging biopsies:
Negative for tumor, all eleven specimens.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, mixed clear cell and endometrioid types, is identified forming an 8.2 x 6.3 x 2.0 cm mass located in the anterior uterine wall. The tumor invades 1.2 cm into the myometrium (total myometrial thickness, 2.9 cm). The tumor involves the

[page 3 of 9]
glandular epithelium of the endocervix. The ectocervix is negative for tumor. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are negative for tumor. Hold over to assess quantity of components of carcinoma on permanent sections.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 650.0 gram uterus with attached bilateral tubes and ovaries and cervix. The uterine serosa is smooth. There is a 8.2 x 6.3 x 2.8 cm mass in the anterior wall of the endometrial cavity with 1.2 cm of invasion into a 2.9 cm myometrial thickness. There are multiple (3) intramural leiomyomas (ranging in size from 0.4 cm to 3.1 cm in greatest dimension). There is a 2.6 x 1.4 x 1.3 cm right ovary with a smooth outer surface and a solid cut surface with a 11.2 x 0.4 cm right fallopian tube. There is a 3.2 x 1.7 x 1.4 cm left ovary with a smooth outer surface and a solid cut surface with a 10.2 x 0.4 cm left fallopian tube. Representative sections submitted.

B. Received fresh labeled "left pelvic lymph nodes, internal" is a 3.0 x 0.7 x 0.4 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "left pelvic lymph nodes, external" is a 6.5 x 5.9 x 1.7 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 4 of 9]
D. Received fresh labeled "left pelvic lymph nodes, common" is a
4.3 x 3.7 x 1.1 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

E. Received fresh labeled "left pelvic lymph nodes, obturator" is a
5.9 x 4.4 x 1.5 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

F. Received fresh labeled "right pelvic lymph nodes, internal" is a
4.5 x 2.6 x 1.0 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

G. Received fresh labeled "right pelvic lymph nodes, external" is a
8.5 x 4.6 x 1.1 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

H. Received fresh labeled "right pelvic lymph nodes, common" is a
3.8 x 2.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

I. Received fresh labeled "right pelvic lymph nodes, obturator" is
a 6.5 x 4.5 x 1.4 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

J. Received fresh labeled "right para-aortic lymph nodes above the
IMA" is a 4.4 x 2.6 x 1.4 cm aggregate of adipose and lymphatic
tissue. All lymphatic tissue submitted.

K. Received fresh labeled "right para-aortic lymph nodes below the
IMA" is a 3.9 x 2.0 x 0.9 cm aggregate of adipose and lymphatic
tissue. All lymphatic tissue submitted.

[page 5 of 9]
L. Received fresh labeled "right gonadal vessels" is a 6.2 cm in length by 1.3 cm in diameter portion of blood vessel. A representative section is submitted.

M. Received fresh labeled "left para-aortic lymph nodes above the IMA" is a 3.4 x 3.1 x 1.1 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

N. Received fresh labeled "left para-aortic lymph nodes below the IMA" is a 2.4 x 1.8 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

O. Received fresh labeled "left gonadal vessels" is a 4.6 cm in length by 0.3 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

P. Received fresh labeled "omentum" is a 48.5 x 18.5 x 2.1 cm portion of omentum. No masses are identified grossly. Lymph nodes are not identified. Representative sections submitted. Grossed by

Q. Received fresh labeled "cul de sac" is a 0.5 x 0.4 x 0.3 cm aggregate of pink-tan soft tissue which is entirely submitted.

R. Received fresh labeled "left colic gutter" is a 1.4 x 1.3 x 0.4 cm aggregate of pink-tan soft tissue which is entirely submitted.

S. Received fresh labeled "left pelvic sidewall" is a 1.5 x 1.0 x 0.9 cm aggregate of pink-tan soft tissue which is entirely submitted.

[page 6 of 9]
T. Received fresh labeled "small bowel serosa" is a 0.2 x 0.2 x 0.2 cm aggregate of pink-tan soft tissue which is entirely submitted.

U. Received fresh labeled "large bowel serosa" is a 0.3 x 0.2 x 0.2 cm aggregate of pink-tan soft tissue which is entirely submitted.

V. Received fresh labeled "bladder peritoneum" is a 1.1 x 1.0 x 0.4 cm aggregate of pink-tan soft tissue which is entirely submitted.

W. Received fresh labeled "right colic gutter" is a 1.0 x 0.5 x 0.5 cm aggregate of pink-tan soft tissue which is entirely submitted.

X. Received fresh labeled "right pelvic sidewall" is a 1.4 x 0.5 x 0.4 cm aggregate of pink-tan soft tissue which is entirely submitted.

Y. Received fresh labeled "small bowel mesentery" is a 0.8 x 0.4 x 0.3 cm aggregate of pink-tan soft tissue which is entirely submitted.

Z. Received fresh labeled "large bowel mesentery" is a 1.0 x 0.4 x 0.3 cm aggregate of pink-tan soft tissue which is entirely submitted.

AA. Received fresh labeled "right diaphragm" is a 0.7 x 0.6 x 0.4 cm aggregate of pink-tan soft tissue which is entirely submitted.

BLOCK SUMMARY:

Part A: Uterus, right and left fallopian tubes and ovaries

- 1 Endometrium dpst invasion-1
- 2 Endometrium dpst invasion-2
- 3 Endometrium tumor-1
- 4 Endometrium tumor-2

[page 7 of 9]
- 5 Endometrium tumor-3
- 6 Lower uterine segment
- 7 Myometrium
- 8 Rt ovary
- 9 Rt fallopian tube
- 10 Lt ovary
- 11 Lt fallopian tube
- 12 12:00 Cervix
- 13 Lower uterine segment
- 14 Fundus mass

Part B: Left Pelvic Lymph Nodes internal
1 Left internal ln ? (B1)

Part C: Left Pelvic Lymph Nodes external
1 Left external lns 3 (C1)
2 Left external lns 2 (C2)
3 Left external lns 1of2 (C3)
4 Left external lns 2of2 (C3)

Part D: Left pelvic lymph nodes - common
1 Left common lns 1 (D1)
2 Left common LNS 2 (D2)
3 Left common LNS 2 (D3)

Part E: Left Pelvic Lymph Nodes obturator
1 Left obturator LNS 3 (E1)
2 Left obturator LNS 2 (E2)
3 Left obturator LNS 3 (E3)
4 Left obturator LNS 5 (E4)

Part F: Right Pelvic Lymph Nodes internal
1 Right internal LNS 4 (F1)
2 Right internal LNS 2 (F2)

Part G: Right Pelvic Lymph Nodes external
1 Right external LN 1 (G1)
2 Right external LN 1 (G2)
3 Right external LNS 2 (G3)
4 Right external LNS 3 (G4)

Part H: Right Pelvic Lymph Nodes common
1 Right common LNS 3 (H1)
2 Right common LN 1 (H2)
3 Right common LNS1of2 (H3)
4 Right common LNS2of2 (H3)

[page 8 of 9]
Part I: Right Pelvic Lymph Nodes obturator

- 1 Right obturator LNS 2 (I1)
- 2 Right obturator LN 1 (I2)
- 3 Right obturator LNS 3 (I3)
- 4 Right obturator LNS 2 (I4)
- 5 Right obturator LNS 2 (I5)
- 6 Right obturator LN 1 (I6)
- 7 Right obturator LN 1 (I7)

Part J: Right Para-aortic Lymph Nodes above IMA

- 1 Rt above IMA LNS 3 (J1)
- 2 Rt above IMA LN 1 (J2)
- 3 Rt above IMA LNS 4 (J3)

Part K: Right Para-aortic Lymph Nodes below IMA

- 1 Rt below IMA LNs-2(K1)
- 2 Rt below IMA LNs-1(K2)

Part L: Right Gonadal vessels

- 1 Right gonadal vessel

Part M: Left Para-aortic Lymph Nodes above IMA

- 1 Lt above IMA LNS 5 (M1)
- 2 Lt above IMA LNS 2 (M2)
- 3 Lt above IMA LNS 2 (M3)

Part N: Left Para-aortic Lymph Nodes below IMA

- 1 Lt below IMA LNS 2 (N1)
- 2 Lt below IMA LNS 2 (N2)

Part O: Left gonadal vessels

- 1 Lt gonadal vessel

Part P: Omentum

- 1 Omentum

Part Q: Cul de sac biopsy

- 1 Cul-de-sac biopsy

Part R: Left colic gutter biopsy

- 1 Lt colic gutter biopsy

Part S: Left pelvic sidewall biopsy

- 1 Lt pelvic sidewall biopsy

Part T: Small bowel serosa biopsy

- 1 Small bowel serosa biopsy

[page 9 of 9]
Part U: Large bowel serosa biopsy
1 Large bowel serosa biopsy

Part V: Bladder peritoneum biopsy
1 Bladder peritoneum biopsy

Part W: Right colic gutter biopsy
1 Rt colic gutter

Part X: Right pelvic sidewall biopsy
1 Rt perlvic sidewall biopsy

Part Y: Small bowel mesentary biopsy
1 Small bowel mesentary bx

Part Z: Large bowel mesentary biopsy
1 Large bowel mesentary biopsy

Part AA: Right diaphragm biopsy
1 Rt diaphragm biopsy

Bior Malignancy History		

Source: NCI Genomic Data Commons file 9c62d5c2-a677-4144-a99d-8b2434a7fd86 (TCGA-D1-A17A.9E0E5CDA-AE46-4ABC-8AF7-C89FE86B7472.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).